Somatic mutation profile of tumor specimen TCGA-DX-A1L1-01A (aliquot TCGA-DX-A1L1-01A-11D-A24N-09) from TCGA case TCGA-DX-A1L1, project TCGA-SARC (Sarcoma). Sex at birth: male; Vital status: Dead; Primary diagnosis: Dedifferentiated liposarcoma; Tissue or organ of origin: Retroperitoneum; Age at diagnosis: 60.8 years (22,218 days).
Specimen TCGA-DX-A1L1-01A: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Solid Tissue; Preservation method: OCT.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) 51282511-4ed4-400e-85ca-8e7266b805c5.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen TCGA-DX-A1L1-10A (Blood Derived Normal), aliquot TCGA-DX-A1L1-10A-01D-A24N-09; read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/61f1930a-ac3b-4eda-822e-03394accc964

The open-access MAF lists 73 somatic variants for this specimen: 51 protein-altering or splice-affecting, 20 silent, 2 other (UTR, intronic, flanking, RNA and similar).
By variant classification: Missense Mutation 42, Silent 20, Nonsense Mutation 4, Splice Site 2, Frame Shift Ins 1, Nonstop Mutation 1, 3'Flank 1, Intron 1, Frame Shift Del 1.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- ADAMTS9 | c.5183G>A p.R1728H | Missense Mutation (SNP) | VAF 17/59 reads (29%) | SIFT tolerated (0.72); PolyPhen benign (0); catalogued as rs202044216, COSV55782203; called by muse, mutect2, varscan2
- CFTR | c.610G>A p.A204T | Missense Mutation (SNP) | VAF 13/58 reads (22%) | SIFT tolerated (0.2); PolyPhen benign (0.051); catalogued as rs748026786, CM087336; ClinVar: uncertain significance; called by muse, mutect2, varscan2
- DGKG | c.1300C>A p.P434T | Missense Mutation (SNP) | VAF 7/37 reads (19%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs753336390, COSV99403412; called by muse, varscan2
- FLG | c.10144C>T p.R3382C | Missense Mutation (SNP) | VAF 44/172 reads (26%) | SIFT deleterious (0); PolyPhen probably damaging (0.962); catalogued as rs147066553, COSV64245007; called by muse, varscan2
- GRM3 | c.547C>T p.R183C | Missense Mutation (SNP) | VAF 30/88 reads (34%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV64467183, COSV64474717; called by muse, mutect2, varscan2
- KRT73 | c.1064G>A p.R355H | Missense Mutation (SNP) | VAF 19/61 reads (31%) | SIFT deleterious (0.01); PolyPhen benign (0.344); catalogued as rs750485971, COSV59838486; called by muse, mutect2, varscan2
- LDAH | c.476G>A p.R159H | Missense Mutation (SNP) | VAF 5/14 reads (36%) | SIFT tolerated (0.32); PolyPhen benign (0.013); catalogued as rs757166551; called by muse, varscan2
- LRRC66 | c.1133C>T p.A378V | Missense Mutation (SNP) | VAF 9/53 reads (17%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as rs1198241954, COSV58633557, COSV58634236; called by muse, mutect2, varscan2
- NGB | c.388C>T p.R130W | Missense Mutation (SNP) | VAF 16/80 reads (20%) | SIFT deleterious (0); PolyPhen possibly damaging (0.679); catalogued as rs750729239; called by muse, mutect2, varscan2
- NOS3 | c.3226G>T p.A1076S | Missense Mutation (SNP) | VAF 14/84 reads (17%) | SIFT deleterious (0); PolyPhen possibly damaging (0.883); catalogued as rs1317783291; called by muse, mutect2, varscan2
- PGK2 | c.202G>T p.D68Y | Missense Mutation (SNP) | VAF 4/11 reads (36%) | SIFT deleterious (0); PolyPhen probably damaging (0.995); catalogued as COSV100505449, COSV99079917; called by muse, mutect2, varscan2
- RIC8A | c.1000G>A p.V334M | Missense Mutation (SNP) | VAF 10/68 reads (15%) | SIFT deleterious (0); PolyPhen probably damaging (0.968); catalogued as rs746737280, COSV57344496; called by muse, mutect2, varscan2
- SEMA6B | c.380G>A p.R127Q | Missense Mutation (SNP) | VAF 18/75 reads (24%) | SIFT tolerated (0.07); PolyPhen probably damaging (0.986); catalogued as rs866405202; called by muse, mutect2, varscan2
- SLC1A6 | c.56G>A p.R19Q | Missense Mutation (SNP) | VAF 11/19 reads (58%) | SIFT tolerated, low confidence (0.35); PolyPhen benign (0); catalogued as rs767982984, COSV55669779; called by muse, mutect2, varscan2
- SOX30 | c.1149G>T p.K383N | Missense Mutation (SNP) | VAF 26/114 reads (23%) | SIFT deleterious (0); PolyPhen probably damaging (0.996); catalogued as COSV53937320; called by muse, mutect2, varscan2
- TLN2 | c.3473G>A p.R1158Q | Missense Mutation (SNP) | VAF 11/67 reads (16%) | SIFT tolerated (0.52); PolyPhen benign (0.003); catalogued as rs759597569, COSV60897432; called by muse, mutect2, varscan2
- TMCC3 | c.493C>T p.R165C | Missense Mutation (SNP) | VAF 6/74 reads (8%) | SIFT deleterious (0); PolyPhen benign (0.02); catalogued as rs374305237, COSV54155538; called by muse, mutect2
- TP53 | c.415A>G p.K139E | Missense Mutation (SNP) | VAF 33/57 reads (58%) | SIFT deleterious (0); PolyPhen probably damaging (0.988); catalogued as rs1212996409, COSV52698907, COSV52754015, COSV53086342, COSV53313307; called by muse, mutect2, varscan2
- ANKRD11 | c.296G>A p.G99D | Missense Mutation (SNP) | VAF 8/76 reads (11%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); called by muse, mutect2
- ATP12A | c.1051C>T p.L351F | Missense Mutation (SNP) | VAF 14/30 reads (47%) | SIFT deleterious (0.01); PolyPhen probably damaging (1); called by muse, mutect2, varscan2
- CACNA2D1 | c.1222+1G>A p.X408_splice | Splice Site (SNP) | VAF 8/22 reads (36%) | called by muse, mutect2, varscan2
- CCDC173 | c.1335T>G p.N445K | Missense Mutation (SNP) | VAF 17/59 reads (29%) | SIFT tolerated (1); PolyPhen benign (0.011); called by muse, mutect2, varscan2
- CCDC178 | c.377G>T p.R126I | Missense Mutation (SNP) | VAF 13/38 reads (34%) | SIFT tolerated (0.07); PolyPhen benign (0.028); called by muse, mutect2, varscan2
- CDH3 | c.1740G>T p.Q580H | Missense Mutation (SNP) | VAF 5/47 reads (11%) | SIFT tolerated (0.51); PolyPhen benign (0.001); called by muse, mutect2
- CHD1 | c.562G>T p.V188F | Missense Mutation (SNP) | VAF 9/110 reads (8%) | SIFT tolerated (0.15); PolyPhen possibly damaging (0.649); called by muse, mutect2
- CYP2A13 | c.798C>A p.D266E | Missense Mutation (SNP) | VAF 12/164 reads (7%) | SIFT deleterious (0); PolyPhen benign (0.392); called by muse, mutect2
- DCDC1 | c.1597A>T p.K533* | Nonsense Mutation (SNP) | VAF 9/32 reads (28%) | called by muse, mutect2, varscan2
- DGKK | c.1823C>A p.A608D | Missense Mutation (SNP) | VAF 5/20 reads (25%) | SIFT deleterious (0); PolyPhen benign (0.258); called by muse, mutect2, varscan2
- DIDO1 | c.5099del p.Y1700Lfs*164 | Frame Shift Del (DEL) | VAF 8/75 reads (11%) | called by mutect2, pindel, varscan2
- DMBT1 | c.287C>A p.S96Y | Missense Mutation (SNP) | VAF 40/160 reads (25%) | SIFT tolerated (0.23); PolyPhen possibly damaging (0.856); called by muse, mutect2, varscan2
- DNAH11 | c.8569G>T p.G2857W | Missense Mutation (SNP) | VAF 10/30 reads (33%) | SIFT deleterious (0); PolyPhen probably damaging (1); called by muse, mutect2, varscan2
- EDRF1 | c.3454G>T p.V1152L (on ENST00000356792 / NM_001202438.2; = p.V1118L on NM_015608.2) | Missense Mutation (SNP) | VAF 3/39 reads (8%) | SIFT tolerated (0.37); PolyPhen benign (0.009); called by muse, mutect2
- FLNB | c.4534C>T p.L1512F | Missense Mutation (SNP) | VAF 23/82 reads (28%) | SIFT tolerated (0.05); PolyPhen probably damaging (0.998); called by muse, mutect2, varscan2
- GPR37 | c.857T>C p.V286A | Missense Mutation (SNP) | VAF 5/77 reads (6%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); called by muse, mutect2
- GRIP1 | c.472G>T p.E158* | Nonsense Mutation (SNP) | VAF 3/19 reads (16%) | called by muse, mutect2
- HNRNPL | c.1234-1G>C p.X412_splice | Splice Site (SNP) | VAF 13/99 reads (13%) | called by muse, mutect2, varscan2
- KRTAP5-2 | c.126T>A p.C42* | Nonsense Mutation (SNP) | VAF 19/78 reads (24%) | called by muse, mutect2, varscan2
- LCP1 | c.1285C>A p.L429I | Missense Mutation (SNP) | VAF 11/66 reads (17%) | SIFT deleterious (0.03); PolyPhen probably damaging (0.999); called by muse, mutect2, varscan2
- LRTM1 | c.472C>G p.L158V | Missense Mutation (SNP) | VAF 3/32 reads (9%) | SIFT deleterious (0); PolyPhen probably damaging (0.961); called by muse, mutect2
- MAB21L1 | c.53A>T p.E18V | Missense Mutation (SNP) | VAF 6/64 reads (9%) | SIFT tolerated (0.18); PolyPhen possibly damaging (0.562); called by muse, mutect2
- MRPL4 | c.337A>G p.K113E | Missense Mutation (SNP) | VAF 12/154 reads (8%) | SIFT tolerated (0.06); PolyPhen benign (0.405); called by muse, mutect2
- PCDH11Y | c.1733G>T p.G578V (on ENST00000400457 / NM_032973.2; = p.G567V on NM_032971.3) | Missense Mutation (SNP) | VAF 6/11 reads (55%) | SIFT deleterious (0); PolyPhen probably damaging (1); called by muse, mutect2, varscan2
- RER1 | c.365G>C p.W122S | Missense Mutation (SNP) | VAF 34/82 reads (41%) | SIFT deleterious (0); PolyPhen probably damaging (1); called by muse, mutect2, varscan2
- SDSL | c.989G>T p.*330Lext*64 | Nonstop Mutation (SNP) | VAF 7/61 reads (11%) | called by muse, mutect2, varscan2
- TLR1 | c.1561G>T p.A521S | Missense Mutation (SNP) | VAF 12/122 reads (10%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.542); called by muse, mutect2
- TRPM8 | c.1996C>A p.Q666K | Missense Mutation (SNP) | VAF 4/40 reads (10%) | SIFT tolerated (1); PolyPhen benign (0.024); called by muse, mutect2, varscan2
- TRPS1 | c.1302C>G p.Y434* (on ENST00000220888 / NM_001330599.2; = p.Y447* on NM_014112.5 and 1 other RefSeq transcript) | Nonsense Mutation (SNP) | VAF 4/18 reads (22%) | called by mutect2, varscan2
- USH2A | c.10791C>A p.S3597R | Missense Mutation (SNP) | VAF 4/25 reads (16%) | SIFT tolerated (0.73); PolyPhen benign (0); called by muse, mutect2, varscan2
- USP47 | c.3360dup p.G1121Rfs*6 (on ENST00000399455 / NM_001372095.1; = p.G1033Rfs*6 on NM_017944.4 and 3 other RefSeq transcripts) | Frame Shift Ins (INS) | VAF 5/18 reads (28%) | called by mutect2, pindel, varscan2
- XPNPEP1 | c.224T>A p.I75N | Missense Mutation (SNP) | VAF 6/46 reads (13%) | SIFT deleterious (0); PolyPhen probably damaging (0.992); called by muse, mutect2, varscan2
- ZNF831 | c.842A>T p.D281V | Missense Mutation (SNP) | VAF 59/161 reads (37%) | SIFT deleterious (0); PolyPhen possibly damaging (0.597); called by muse, mutect2, varscan2
- ADGRB3 | c.2532C>A p.T844= | Silent (SNP) | VAF 14/64 reads (22%) | catalogued as COSV53237310, COSV53243546; called by muse, mutect2, varscan2
- BRINP2 | c.822T>C p.A274= | Silent (SNP) | VAF 13/49 reads (27%) | called by muse, mutect2, varscan2
- CHAT | c.414G>A p.P138= | Silent (SNP) | VAF 17/63 reads (27%) | catalogued as rs199675090, COSV60319880; called by muse, mutect2, varscan2
- CREB3L3 | c.1329T>C p.P443= | Silent (SNP) | VAF 4/44 reads (9%) | called by muse, mutect2
- DNAJB9 | c.369C>A p.G123= | Silent (SNP) | VAF 9/63 reads (14%) | called by muse, mutect2, varscan2
- EDN3 | c.375G>T p.V125= | Silent (SNP) | VAF 14/117 reads (12%) | called by muse, mutect2, varscan2
- EIF4E | c.12C>G p.V4= | Silent (SNP) | VAF 8/105 reads (8%) | catalogued as COSV55188188; called by muse, mutect2
- GMPR2 | c.945G>T p.T315= (on ENST00000355299 / NM_001351022.2; = p.T333= on NM_016576.5) | Silent (SNP) | VAF 9/55 reads (16%) | called by muse, mutect2, varscan2
- GPR6 | c.507C>G p.S169= | Silent (SNP) | VAF 6/57 reads (11%) | called by muse, mutect2, varscan2
- GSTCD | c.1746A>T p.P582= (on ENST00000360505 / NM_001031720.3; = p.P495= on NM_024751.3) | Silent (SNP) | VAF 8/42 reads (19%) | catalogued as rs1216938569; called by muse, mutect2, varscan2
- H2BC18 | c.177C>T p.A59= | Silent (SNP) | VAF 97/187 reads (52%) | catalogued as rs782055162, COSV58943679; called by muse, mutect2, varscan2
- MATN3 | c.732C>T p.Y244= | Silent (SNP) | VAF 21/62 reads (34%) | catalogued as rs371740669; called by muse, mutect2, varscan2
- MMAA | c.855G>T p.L285= | Silent (SNP) | VAF 6/72 reads (8%) | called by muse, mutect2
- PAX4 | c.489G>T p.R163= | Silent (SNP) | VAF 18/93 reads (19%) | catalogued as COSV58388457; called by muse, mutect2, varscan2
- PCDHB6 | c.1396C>T p.L466= | Silent (SNP) | VAF 37/239 reads (15%) | catalogued as COSV99169909; called by muse, mutect2, varscan2
- PIGR | c.846C>T p.V282= | Silent (SNP) | VAF 8/48 reads (17%) | catalogued as rs142351595; called by muse, mutect2, varscan2
- REXO4 | c.1191G>A p.V397= | Silent (SNP) | VAF 68/118 reads (58%) | called by muse, mutect2, varscan2
- REXO4 | c.1119G>T p.G373= | Silent (SNP) | VAF 94/198 reads (47%) | called by muse, varscan2
- RPL3L | c.225G>A p.A75= | Silent (SNP) | VAF 9/70 reads (13%) | catalogued as rs924963120; called by muse, mutect2, varscan2
- SORCS3 | c.2358C>T p.S786= | Silent (SNP) | VAF 7/26 reads (27%) | catalogued as rs773048107; called by muse, mutect2, varscan2
- NOP56 | c.1160-89G>C | Intron (SNP) | VAF 11/102 reads (11%) | called by muse, mutect2, varscan2
- TEX2 | chr17:64146455 A>T | 3'Flank (SNP) | VAF 32/60 reads (53%) | called by muse, mutect2, varscan2
